Gene-level copy-number profile of tumor specimen HTMCP-03-06-02108-01B from CGCI case HTMCP-03-06-02108, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02108-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1233fb43-6980-4639-8905-1af64d68c173.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02108-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/9af5af34-8fbb-4d58-ad1a-f9b88369bfc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 5,006; copy number 2: 42,443; copy number 3: 8,943; copy number 4: 1,065; copy number 5: 523; copy number 6: 138; copy number 8: 46; copy number 9: 71; copy number 10: 9; copy number 14: 29; copy number 15: 4; copy number 37: 23; copy number 44: 24; copy number 48: 12.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–2): AC243772.3, RNU1-68P.
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–2): LRRN3.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:12,033,646–12,043,670, 2 genes: AC107918.1, DEFB131C.
- chr8:12,115,767–12,665,588, 28 genes (within-gene range 0–1): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2.
- chr14:18,562,928–18,602,129, 3 genes (within-gene range 0–4): CR383656.13, CR383656.9, OR11H12.
- chr17:18,511,262–18,521,252, 1 gene (within-gene range 0–1): USP32P2.
- chr22:18,733,914–18,843,399, 4 genes (within-gene range 0–7): FAM230E, GGT3P, AC008132.2, E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 879 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:83,218,890–91,580,863, 225 genes, copy number 5–48 (broad region; genes not listed).
- chr2:188,974,373–191,425,389, 50 genes, copy number 5–6: COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr5:16,615,926–16,681,905, 1 gene, copy number 5 (within-gene range 4–5): AC024588.1.
- chr5:16,661,907–16,941,951, 4 genes, copy number 5: MYO10, RNA5SP179, RPS26P28, RNU6-660P.
- chr5:36,861,736–37,753,435, 17 genes, copy number 5: AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr11:67,398,181–71,252,577, 123 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:81,821,272–82,718,299, 1 gene, copy number 5 (within-gene range 4–5): MIR4300HG.
- chr11:82,603,529–83,423,516, 31 genes, copy number 5: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr13:87,219,004–87,380,258, 2 genes, copy number 6: UBBP5, LIN28AP2.
- chr17:55,882,301–71,013,587, 418 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:8,680,538–8,680,934, 1 gene, copy number 14: CR381572.2.
- chr22:18,636,445–18,719,341, 3 genes, copy number 5: CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,906,028–18,947,732, 3 genes, copy number 9 (within-gene range 2–9): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 4,009. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
